Gene-level copy-number profile of tumor specimen TCGA-24-1930-01A from TCGA case TCGA-24-1930, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.1 years (19,387 days).
Specimen TCGA-24-1930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2a2cad37-1da4-4b68-b16d-6d2ba3ce6ab8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1930-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dae7c4ed-893a-4966-b7e6-8e483c54d23e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 936; copy number 2: 24,494; copy number 3: 17,788; copy number 4: 14,748; copy number 5: 715; copy number 6: 1,123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1930-01): tumor purity 0.66, ploidy 2.97, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,529,761–26,602,432, 5 genes (within-gene range 0–2): RPS6KA1, MIR1976, RN7SL679P, Y_RNA, RNU7-29P.
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,835 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–135,439,888, 712 genes, copy number 5 (broad region; genes not listed).
- chr3:136,808,551–198,222,513, 1,072 genes, copy number 6 (broad region; genes not listed).
- chr12:100,717,526–103,016,095, 51 genes, copy number 6 (within-gene range 4–6): ANO4, AC138360.1, AC063947.1, SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20, ARL1, AC063948.1, RNU6-1068P, RPS27P23, Y_RNA, RNU5E-5P, RNA5SP367, SPIC, MYBPC1, AC117505.1, AC010205.1, CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1, LINC00485, PAH, AC026108.1, ASCL1, AC026108.2.

Autosomal genes at a single copy (total copy number 1): 936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
